FM case AD7181 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified parts of biliary tract.
https://portal.gdc.cancer.gov/cases/3899cbfa-c0fe-4d67-9875-e3e8b42ea4be

Male, 64.3 years: diagnosis not reported by GDC of the biliary tract; metastasis biopsied or resected from the gallbladder. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
